Somatic mutation profile of tumor specimen ALCH-AFAD-TTP1-A (aliquot ALCH-AFAD-TTP1-A-1-0-D-A667-36) from ALCHEMIST case ALCH-AFAD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.6 years (26,146 days).
Specimen ALCH-AFAD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80ae4a6f-ef88-4cb4-990b-fdcf69ba4321.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFAD-NB1-A (Blood Derived Normal), aliquot ALCH-AFAD-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11fb94cc-3ada-4347-9d2c-c590458325e8

The open-access MAF lists 524 somatic variants for this specimen: 369 protein-altering or splice-affecting, 95 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 313, Silent 95, Intron 27, Nonsense Mutation 26, Splice Site 14, RNA 10, 5'UTR 9, 3'UTR 6, Frame Shift Del 5, Splice Region 4, 3'Flank 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14503G>C p.E4835Q | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.16); catalogued as rs758264366; called by muse, mutect2, varscan2
- ABCC11 | c.699G>C p.R233S | Missense Mutation (SNP) | VAF 83/437 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62322774; called by muse, mutect2, varscan2
- ABLIM3 | c.416G>C p.S139T | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100448107; called by muse, mutect2, varscan2
- AC005833.1 | c.1394A>G p.Y465C | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0); catalogued as rs190584465; called by muse, mutect2, varscan2
- ANKRD30A | c.1952C>A p.S651Y (on ENST00000611781; = p.S595Y on NM_052997.2) | Missense Mutation (SNP) | VAF 21/522 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1339555665, COSV64624153; called by muse, mutect2
- ANO2 | c.2645C>A p.P882Q (on ENST00000356134 / NM_001278597.3; = p.P886Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372358207; called by muse, mutect2, varscan2
- AP5Z1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV100804115, COSV62244176; called by muse, mutect2
- ARID1A | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.452); catalogued as rs1052208440, COSV61373280; called by muse, mutect2, varscan2
- ASL | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs868834862, CM141244, COSV59189662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATIC | c.922+1G>A p.X308_splice | Splice Site (SNP) | VAF 37/353 reads (10%) | catalogued as rs143359980, COSV99377881; called by muse, mutect2, varscan2
- BCAS3 | c.2566G>T p.E856* (on ENST00000390652 / NM_001353144.2; = p.E841* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV66774308; called by muse, varscan2
- CACNA1E | c.4465G>T p.A1489S | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV62393791; called by muse, mutect2
- CARS1 | c.1768G>T p.V590L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV53450301; called by muse, mutect2, varscan2
- CCT3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs746245572, COSV55288933; called by muse, mutect2, varscan2
- CDH1 | c.1997A>C p.N666T | Missense Mutation (SNP) | VAF 140/584 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.266); catalogued as COSV55728349; called by muse, mutect2, varscan2
- CNOT6L | c.1547A>G p.N516S (on ENST00000504123 / NM_001286790.2; = p.N511S on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/605 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs200590761; called by muse, mutect2
- CNTF | c.500A>C p.Q167P | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV100284579; called by muse, mutect2
- CNTN5 | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV54362432; called by muse, mutect2, varscan2
- COL11A1 | c.5020G>C p.E1674Q | Missense Mutation (SNP) | VAF 103/816 reads (13%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.995); catalogued as COSV62186769; called by muse, mutect2, varscan2
- CSMD3 | c.8252G>T p.R2751I | Missense Mutation (SNP) | VAF 40/620 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99847340; called by muse, mutect2
- DAAM1 | c.2287G>C p.E763Q | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs1251308743; called by muse, mutect2
- DCAF12L1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1165225797; called by muse, mutect2, varscan2
- DGKQ | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56616382; called by muse, varscan2
- DIPK1A | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV64791467; called by muse, mutect2
- DISP3 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs747079328; called by muse, mutect2, varscan2
- DMBT1 | c.7061G>A p.W2354* (on ENST00000338354 / NM_001377530.1; = p.W1597* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 16/430 reads (4%) | catalogued as COSV100354098; called by muse, mutect2
- DNAH11 | c.13179G>A p.M4393I | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs777813597; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAH17 | c.9274G>C p.E3092Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV101103407; called by muse, mutect2, varscan2
- DNAH17 | c.8593G>T p.E2865* | Nonsense Mutation (SNP) | VAF 35/187 reads (19%) | catalogued as COSV67753634; called by muse, mutect2, varscan2
- DNAH17 | c.5228G>A p.G1743E | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1185468301; called by muse, mutect2
- DNAJC1 | c.746A>T p.Y249F | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100981447; called by muse, mutect2, varscan2
- DSEL | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV59491515; called by muse, mutect2, varscan2
- DSTYK | c.2060A>T p.D687V | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100904439; called by muse, mutect2
- EPHA8 | c.2569C>A p.L857M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99385608; called by muse, mutect2, varscan2
- EPHB1 | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67670167; called by muse, mutect2, varscan2
- ERBB2 | c.2493G>A p.K831= | Splice Region (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99507228; called by muse, mutect2, varscan2
- ESCO2 | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 134/789 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs369056136; called by muse, mutect2, varscan2
- FAM155B | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV52935094; called by muse, mutect2, varscan2
- FAM163A | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs778086353; called by muse, mutect2, varscan2
- FAM83B | c.2725G>T p.E909* | Nonsense Mutation (SNP) | VAF 56/452 reads (12%) | catalogued as COSV60921665; called by muse, mutect2, varscan2
- FAT2 | c.1525C>A p.P509T | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.137); catalogued as rs779680737; called by muse, mutect2
- FAT4 | c.7093G>T p.A2365S | Missense Mutation (SNP) | VAF 30/610 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1349715241; called by muse, mutect2
- FMO4 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63001945; called by muse, mutect2, varscan2
- FSIP2 | c.15947C>A p.A5316E | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1358005615; called by muse, mutect2
- GABRB3 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54662144; called by muse, mutect2
- GAL3ST4 | c.808C>A p.R270S | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57588370; called by muse, mutect2, varscan2
- GALNT9 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs782209642, COSV104410801; called by muse, mutect2, varscan2
- GLB1L2 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs141480972; called by muse, mutect2, varscan2
- GLYATL3 | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as COSV64591586; called by muse, mutect2
- GPAT3 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52360317; called by muse, mutect2, varscan2
- GPLD1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 67/323 reads (21%) | catalogued as COSV57756279; called by muse, mutect2, varscan2
- GRID2 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 49/648 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.264); catalogued as COSV99948668; called by muse, mutect2
- GRK3 | c.601G>T p.G201* | Nonsense Mutation (SNP) | VAF 28/466 reads (6%) | catalogued as COSV60800240; called by muse, mutect2
- GRK3 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60798971; called by muse, mutect2
- GRM8 | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1305115149; called by muse, mutect2, varscan2
- HNF4A | c.171C>G p.S57R | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs199678287; called by muse, mutect2, varscan2
- HSPA6 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.287); catalogued as rs763881216, COSV100553755, COSV59061575; called by muse, mutect2
- IFT74 | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1459540882; called by muse, mutect2, varscan2
- IGFBP1 | c.182del p.P61Rfs*69 | Frame Shift Del (DEL) | VAF 21/108 reads (19%) | catalogued as COSV51875214; called by mutect2, pindel, varscan2
- INPP5D | c.2822C>A p.A941D (on ENST00000445964 / NM_001017915.3; = p.A940D on NM_005541.5) | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as rs753092943; called by muse, mutect2, varscan2
- ITK | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 112/856 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM121080, COSV101439808, COSV70061950, COSV70062223; called by muse, mutect2, varscan2
- KIF18A | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54183908; called by muse, mutect2, varscan2
- KLHL1 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100918162, COSV64777211; called by muse, mutect2
- KRTAP22-1 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 70/675 reads (10%) | PolyPhen benign (0.006); catalogued as COSV58182090, COSV58182288; called by muse, mutect2
- LHCGR | c.639G>T p.M213I | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54295708; called by muse, mutect2, varscan2
- LRATD2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs771634972, COSV100513626, COSV100513644; called by muse, mutect2, varscan2
- LRP1B | c.3599C>A p.P1200H | Missense Mutation (SNP) | VAF 53/451 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV101257887; called by muse, mutect2, varscan2
- MAP1B | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 76/508 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99702557; called by muse, mutect2, varscan2
- MIGA1 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV100889811; called by muse, mutect2, varscan2
- MINPP1 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 62/758 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV64354839; called by muse, mutect2
- MYH3 | c.4056G>T p.Q1352H | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1437714349; called by muse, mutect2
- NAV3 | c.1852C>G p.Q618E | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57103325; called by muse, mutect2
- NTNG2 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100647461; called by muse, mutect2, varscan2
- OR10X1 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 177/718 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV63767716, COSV63767989; called by muse, mutect2, varscan2
- OR2F1 | c.291T>G p.C97W | Missense Mutation (SNP) | VAF 81/412 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773358008; called by muse, mutect2, varscan2
- OR51B5 | c.64C>A p.H22N | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs566514307; called by muse, mutect2, varscan2
- OR56A4 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 33/454 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs748087343, COSV58109480; called by muse, mutect2
- OR5J2 | c.859C>A p.L287M | Missense Mutation (SNP) | VAF 72/465 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100398975; called by muse, mutect2, varscan2
- OR8U1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1300922441, COSV100164135; called by muse, mutect2, varscan2
- PCDHA1 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65374859, COSV65376141; called by muse, mutect2, varscan2
- PCDHGA3 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV53966423, COSV53991933; called by muse, mutect2, varscan2
- POM121L12 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV68692825; called by muse, mutect2
- PRDM9 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 65/678 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs1192189339, COSV57008249; called by muse, mutect2
- PRSS21 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs762636042; called by muse, mutect2, varscan2
- PTPRO | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 77/526 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV55507494; called by muse, mutect2, varscan2
- RAD51AP2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 44/635 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV67587583; called by muse, mutect2
- RAMP3 | c.59-1G>T p.X20_splice | Splice Site (SNP) | VAF 16/93 reads (17%) | catalogued as COSV54244798; called by muse, mutect2, varscan2
- RGS13 | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV101232259; called by muse, mutect2
- RNF123 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.49); catalogued as COSV100570493; called by muse, mutect2, varscan2
- RNF150 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as rs151203574; called by muse, mutect2, varscan2
- RNF222 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs752545929; called by muse, mutect2, varscan2
- SLC16A9 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101264295; called by muse, mutect2, varscan2
- SMAD2 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 701/1598 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100053304, COSV51013553; called by muse, mutect2, varscan2
- SMARCA2 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61805119; called by muse, mutect2
- SOX30 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 83/616 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.058); catalogued as rs781043876; called by muse, mutect2, varscan2
- TAB2 | c.1628G>A p.R543K | Missense Mutation (SNP) | VAF 96/1000 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV53852272, COSV53854927; called by muse, mutect2
- TBC1D12 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV56557558; called by muse, mutect2, varscan2
- TMEM132B | c.2762C>G p.A921G | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV54755234, COSV54760348; called by muse, mutect2, varscan2
- TMEM151B | c.520C>G p.R174G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101442013, COSV71286900; called by muse, mutect2
- TMEM183A | c.943C>T p.L315= | Splice Region (SNP) | VAF 12/156 reads (8%) | catalogued as COSV65887990; called by muse, mutect2
- TMEM237 | c.943+1G>A p.X315_splice (on ENST00000409883 / NM_001044385.3; = p.X307_splice on NM_152388.4) | Splice Site (SNP) | VAF 37/308 reads (12%) | catalogued as CS1110085; called by muse, mutect2, varscan2
- TMTC1 | c.880C>A p.P294T (on ENST00000539277 / NM_001193451.2; = p.P186T on NM_175861.3) | Missense Mutation (SNP) | VAF 101/358 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55478655, COSV55479749; called by muse, mutect2, varscan2
- TP53 | c.370dup p.C124Lfs*25 | Frame Shift Ins (INS) | VAF 33/135 reads (24%) | catalogued as COSV52717910, COSV53118583; called by mutect2, pindel, varscan2
- TPBG | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs144737771; called by muse, mutect2, varscan2
- TRIM42 | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | catalogued as COSV53884645; called by mutect2, varscan2
- TRIM51 | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 115/924 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99792738; called by muse, mutect2, varscan2
- TTN | c.82286del p.G27429Efs*7 (on ENST00000591111; = p.G20005Efs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 80/559 reads (14%) | catalogued as COSV100625979; called by mutect2, pindel, varscan2
- UCP2 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM131727; called by muse, mutect2, varscan2
- WDR7 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs758151746; called by muse, mutect2, varscan2
- ZFHX4 | c.9803C>A p.P3268H | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51506448, COSV99261630; called by muse, mutect2, varscan2
- ZNF257 | c.887G>C p.W296S | Missense Mutation (SNP) | VAF 79/505 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.581); catalogued as COSV71312844; called by muse, mutect2, varscan2
- AARS2 | c.2794-1G>T p.X932_splice | Splice Site (SNP) | VAF 30/259 reads (12%) | called by muse, mutect2, varscan2
- ABCB5 | c.2726+1G>T p.X909_splice (on ENST00000404938 / NM_001163941.2; = p.X464_splice on NM_178559.6) | Splice Site (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- AC069544.2 | c.391C>G p.P131A | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- ADAM18 | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- ADAMTS12 | c.2948G>A p.R983K | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP13 | c.8202C>G p.I2734M (on ENST00000394518 / NM_007200.5; = p.I2738M on NM_006738.6) | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ANK2 | c.3199G>T p.G1067W | Missense Mutation (SNP) | VAF 35/543 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK2 | c.9485C>G p.S3162* | Nonsense Mutation (SNP) | VAF 37/615 reads (6%) | called by muse, mutect2
- ANKIB1 | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ANKRD33B | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 23/278 reads (8%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.876); called by muse, mutect2
- AOX1 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 77/550 reads (14%) | called by muse, mutect2, varscan2
- APP | c.2270A>T p.Y757F | Missense Mutation (SNP) | VAF 85/661 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF6 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP2A1 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP8A2 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BAZ1A | c.3652G>A p.V1218M | Missense Mutation (SNP) | VAF 257/1098 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNC2 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- BPIFB2 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BPIFB6 | c.945C>G p.I315M | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.13); called by muse, mutect2
- BPTF | c.7266G>T p.Q2422H | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- BRWD3 | c.5374G>T p.A1792S | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BRWD3 | c.1867G>T p.V623L | Missense Mutation (SNP) | VAF 24/319 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, mutect2
- BTG1 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- C1orf87 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C6orf15 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); called by muse, mutect2
- CACNA1B | c.3356G>T p.S1119I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CACNA1G | c.6004G>A p.D2002N | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- CASP8AP2 | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CCAR1 | c.142T>A p.L48M | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC141 | c.2891T>G p.V964G | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- CCDC57 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CCHCR1 | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CD70 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEBPB | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CENPE | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEP112 | c.390T>A p.S130R | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.136); called by muse, mutect2
- CEP192 | c.6788C>A p.P2263Q | Missense Mutation (SNP) | VAF 48/525 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CERKL | c.1152-1G>T p.X384_splice (on ENST00000339098 / NM_001030311.2; = p.X358_splice on NM_201548.5) | Splice Site (SNP) | VAF 27/752 reads (4%) | called by muse, mutect2
- CNTN4 | c.897T>G p.N299K | Missense Mutation (SNP) | VAF 71/723 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTN5 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN6 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 40/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP5 | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- COL22A1 | c.3703T>G p.L1235V | Missense Mutation (SNP) | VAF 25/527 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- COL4A2 | c.4219dup p.Q1407Pfs*49 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel, varscan2
- COL6A3 | c.9326C>A p.T3109K | Missense Mutation (SNP) | VAF 51/708 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2
- COL6A6 | c.3484G>T p.D1162Y | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CPS1 | c.2842G>T p.A948S | Missense Mutation (SNP) | VAF 110/966 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CPS1 | c.3622C>G p.L1208V | Missense Mutation (SNP) | VAF 70/652 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, varscan2
- CUBN | c.3883G>T p.G1295W | Missense Mutation (SNP) | VAF 149/748 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DEFB121 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- DGKB | c.2413T>A p.*805Kext*13 | Nonstop Mutation (SNP) | VAF 48/506 reads (9%) | called by muse, mutect2
- DGKK | c.2658-1G>A p.X886_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- DLG1 | c.2345G>T p.G782V (on ENST00000419354 / NM_001290983.1; = p.G804V on NM_004087.2) | Missense Mutation (SNP) | VAF 78/359 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG1 | c.2344G>T p.G782C (on ENST00000419354 / NM_001290983.1; = p.G804C on NM_004087.2) | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP4 | c.727A>T p.M243L | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMGDH | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DNAH10 | c.5249G>A p.W1750* (on ENST00000409039; = p.W1689* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 120/311 reads (39%) | called by muse, mutect2, varscan2
- DNAH12 | c.7118G>T p.G2373V (on ENST00000351747; = p.G3241V on NM_001366028.2) | Missense Mutation (SNP) | VAF 31/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DNAH14 | c.5133G>T p.M1711I (on ENST00000445597; = p.M2116I on NM_001367479.1) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.145); called by muse, mutect2
- DNAH14 | c.9193A>G p.I3065V (on ENST00000445597; = p.I3829V on NM_001367479.1) | Missense Mutation (SNP) | VAF 75/660 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DNAJC5G | c.439T>G p.C147G | Missense Mutation (SNP) | VAF 25/460 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- DOCK4 | c.3239_3245delinsT p.D1080_R1082delinsV | In Frame Del (DEL) | VAF 56/434 reads (13%) | called by pindel, varscan2*
- DSCAM | c.4651T>A p.C1551S | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.039); called by muse, varscan2
- DSN1 | c.701A>T p.Q234L | Missense Mutation (SNP) | VAF 36/599 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2
- DSTYK | c.2059G>C p.D687H | Missense Mutation (SNP) | VAF 37/396 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- EBF2 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 52/449 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EFHB | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 94/579 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ENOX1 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 19/466 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2
- ENPP2 | c.2239C>A p.H747N (on ENST00000075322 / NM_001040092.3; = p.H799N on NM_006209.5) | Missense Mutation (SNP) | VAF 51/490 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERCC6L | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ESCO2 | c.264C>G p.N88K | Missense Mutation (SNP) | VAF 19/502 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- FAM160B1 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 28/682 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- FGA | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- FMN2 | c.4583G>T p.S1528I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FOXP2 | c.2124G>T p.E708D | Missense Mutation (SNP) | VAF 134/667 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GAD2 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- GLB1 | c.1510A>T p.N504Y | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- GPR3 | c.367A>G p.S123G | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRIK3 | c.1129C>G p.R377G | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GRM7 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 60/450 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- HOXA2 | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 33/373 reads (9%) | called by muse, mutect2
- IDI1 | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- IGLON5 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.071); called by mutect2, varscan2
- ILRUN | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2
- INPP4A | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGA5 | c.2727+1G>T p.X909_splice | Splice Site (SNP) | VAF 24/141 reads (17%) | called by muse, mutect2, varscan2
- ITGA5 | c.2429G>T p.W810L | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH6 | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6B | c.3372+1_3372+2del p.X1124_splice | Splice Site (DEL) | VAF 63/431 reads (15%) | called by pindel, varscan2
- KCNA5 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2
- KIAA1109 | c.10786A>T p.S3596C | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIAA1549L | c.4678G>A p.E1560K (on ENST00000321505; = p.E1857K on NM_012194.3) | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KIAA1549L | c.5211C>A p.N1737K (on ENST00000321505; = p.N2034K on NM_012194.3) | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KIF1A | c.1592T>A p.L531Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- KRT73 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LCE2C | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT tolerated, low confidence (0.85); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCT | c.539A>G p.K180R | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGALS9B | c.802C>A p.H268N (on ENST00000423676 / NM_001367292.1; = p.H267N on NM_001042685.2) | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LGR6 | c.677G>A p.G226E (on ENST00000367278 / NM_001017403.1; = p.G174E on NM_021636.3) | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LOXHD1 | c.4081C>A p.R1361S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- LRP2 | c.13096G>A p.E4366K | Missense Mutation (SNP) | VAF 91/558 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LRP5 | c.1556G>A p.W519* | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- LRRC6 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 32/546 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2
- LRRTM4 | c.-80C>A | Splice Region (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- LTBP4 | c.1921G>A p.D641N (on ENST00000308370 / NM_001042544.1; = p.D604N on NM_003573.2) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAGEB16 | c.242del p.S81Mfs*41 | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- MAP1A | c.5837C>G p.P1946R | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.299); called by muse, mutect2
- MAP3K15 | c.2441A>T p.Q814L | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARF1 | c.2648C>G p.T883R | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, varscan2
- MARS1 | c.201-5G>T | Splice Region (SNP) | VAF 34/197 reads (17%) | called by muse, mutect2, varscan2
- MASP2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MASTL | c.2207G>T p.G736V (on ENST00000375940 / NM_001372029.1; = p.G735V on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.424); called by muse, mutect2
- MED14 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- MEGF10 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF11 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.463); called by muse, mutect2
- METTL25 | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MEX3D | c.1327G>T p.V443L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MGA | c.5644C>T p.Q1882* (on ENST00000219905 / NM_001164273.1; = p.Q1673* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- MINAR1 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMEL1 | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- MOB3B | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2
- MS4A12 | c.653G>T p.C218F | Missense Mutation (SNP) | VAF 54/528 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.088); called by muse, mutect2
- MS4A18 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MSTO1 | c.1374G>T p.Q458H | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.41459G>T p.R13820M | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MYH1 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 74/587 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NCAPD3 | c.3608C>T p.P1203L | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEURL1 | c.1602C>A p.Y534* | Nonsense Mutation (SNP) | VAF 67/226 reads (30%) | called by muse, mutect2, varscan2
- NID2 | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NLRP3 | c.2629G>T p.A877S | Missense Mutation (SNP) | VAF 49/604 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2
- NLRP5 | c.2069G>T p.C690F | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NOC2L | c.1490C>A p.S497Y | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); called by muse, mutect2
- NPC1L1 | c.2431T>A p.C811S | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, mutect2
- NPIPB7 | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- NR2E1 | c.25A>T p.S9C | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); called by muse, mutect2
- NTF3 | c.434A>T p.H145L | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NUMA1 | c.1119+1G>T p.X373_splice | Splice Site (SNP) | VAF 26/287 reads (9%) | called by muse, mutect2
- OAS3 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 40/256 reads (16%) | called by mutect2, varscan2
- OBSCN | c.7058C>T p.A2353V | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- OR10R2 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 68/398 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- OR1I1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2AK2 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR2AP1 | c.750C>A p.Y250* | Nonsense Mutation (SNP) | VAF 67/453 reads (15%) | called by muse, mutect2, varscan2
- OR2M2 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 81/552 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C13 | c.590T>G p.I197S | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); called by muse, mutect2
- OR52D1 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5D14 | c.594C>G p.H198Q | Missense Mutation (SNP) | VAF 86/562 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR9Q1 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL8 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 23/874 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2
- OTOF | c.5860G>A p.A1954T (on ENST00000272371 / NM_194248.3; = p.A1187T on NM_004802.4) | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2
- P2RX5 | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 78/495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- P2RX6 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- PAIP1 | c.1080-2A>T p.X360_splice | Splice Site (SNP) | VAF 55/373 reads (15%) | called by muse, mutect2, varscan2
- PCDH10 | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDH15 | c.2614G>T p.G872* | Nonsense Mutation (SNP) | VAF 148/712 reads (21%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1876A>G p.T626A | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- PCDHB15 | c.1860C>A p.H620Q | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGA2 | c.1242G>T p.Q414H | Missense Mutation (SNP) | VAF 86/465 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PDSS1 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 170/753 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- PERM1 | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PGK2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 36/459 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); called by muse, mutect2
- PKHD1 | c.8279G>T p.G2760V | Missense Mutation (SNP) | VAF 86/673 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCL1 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 79/788 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PLPPR4 | c.879C>A p.C293* | Nonsense Mutation (SNP) | VAF 28/356 reads (8%) | called by muse, mutect2
- POTEF | c.2503G>C p.A835P | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- POU6F2 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- PRB4 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PSG3 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PSG4 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- PTGS2 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRK | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PTPRN | c.2729G>T p.S910I | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by mutect2, varscan2
- PZP | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- RBM3 | c.317-2A>T p.X106_splice | Splice Site (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- RFX3 | c.1436A>C p.Q479P | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFX7 | c.217G>A p.G73S (on ENST00000559447 / NM_001368074.1; = p.G170S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIMS1 | c.3404G>T p.R1135I | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, varscan2
- RND3 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1 | c.1432A>T p.I478F | Missense Mutation (SNP) | VAF 24/587 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- RPS15 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- RTTN | c.6578A>T p.Y2193F | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RYR1 | c.6519G>T p.Q2173H | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2
- RYR1 | c.6520G>T p.E2174* | Nonsense Mutation (SNP) | VAF 16/233 reads (7%) | called by muse, mutect2
- RYR2 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 73/594 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SAAL1 | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- SAMD7 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SDCCAG8 | c.421-1G>A p.X141_splice | Splice Site (SNP) | VAF 38/480 reads (8%) | called by muse, mutect2
- SDCCAG8 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 37/485 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- SEMA5B | c.2831C>A p.P944Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SF3A1 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 40/377 reads (11%) | called by muse, mutect2, varscan2
- SFSWAP | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- SGPP1 | c.676del p.R226Afs*10 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.1976A>G p.K659R | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 4/44 reads (9%) | PolyPhen benign (0); called by muse, mutect2
- SIRT5 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC24A2 | c.1984T>A p.*662Kext*11 | Nonstop Mutation (SNP) | VAF 76/630 reads (12%) | called by muse, mutect2, varscan2
- SLC28A3 | c.1957G>T p.A653S | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC2A13 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 45/710 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2
- SLC35A5 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 80/330 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLC6A1 | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SMARCAD1 | c.706-1G>T p.X236_splice | Splice Site (SNP) | VAF 32/418 reads (8%) | called by muse, mutect2
- SMC1B | c.854A>T p.K285I | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SNX9 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 88/431 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SORCS3 | c.588C>A p.H196Q | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SORCS3 | c.3003G>C p.Q1001H | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- SPATA48 | c.884G>T p.W295L | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAG1 | c.637T>A p.S213T | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAT5B | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 21/301 reads (7%) | called by muse, mutect2
- STK11 | c.531_535delinsG p.I177Mfs*109 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by pindel, varscan2*
- STXBP5 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 130/624 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); called by muse, varscan2
- SVIL | c.1494A>T p.Q498H | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 38/812 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- TEK | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 62/736 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.333); called by muse, mutect2
- THSD7A | c.3991C>A p.Q1331K | Missense Mutation (SNP) | VAF 41/432 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TLR8 | c.3123C>A p.Y1041* (on ENST00000218032 / NM_138636.5; = p.Y1059* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | called by muse, varscan2
- TLX2 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2
- TMEM101 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- TMEM132C | c.825C>A p.Y275* | Nonsense Mutation (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2
- TMEM132D | c.2271dup p.A758Cfs*17 | Frame Shift Ins (INS) | VAF 40/392 reads (10%) | called by mutect2, varscan2
- TMPRSS11F | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 22/365 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.282); called by muse, mutect2
- TNS1 | c.3844A>T p.N1282Y | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- TOMM6 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 19/343 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); called by muse, mutect2
- TRBV7-1 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TREM2 | c.578T>A p.L193H | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- TRHR | c.932T>A p.L311H | Missense Mutation (SNP) | VAF 66/1006 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- TRIM77 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- TRPS1 | c.807C>A p.N269K (on ENST00000220888 / NM_001330599.2; = p.N282K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTC14 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2
- TTN | c.60132T>A p.S20044R (on ENST00000591111; = p.S12620R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/306 reads (5%) | PolyPhen possibly damaging (0.812); called by muse, mutect2
- TTN | c.12199C>A p.L4067I (on ENST00000591111; = p.L4021I on NM_003319.4) | Missense Mutation (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- TUBA3C | c.978A>T p.K326N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); called by mutect2, varscan2
- UBE2NL | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, varscan2
- UBTFL1 | c.294C>A p.D98E | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1136G>C p.S379T | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); called by muse, mutect2
- UNC80 | c.7435G>T p.E2479* | Nonsense Mutation (SNP) | VAF 48/450 reads (11%) | called by muse, mutect2, varscan2
- URB1 | c.1442A>T p.E481V | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- USF3 | c.3322A>T p.T1108S | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- USP16 | c.389A>T p.Q130L | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP43 | c.2865G>T p.W955C | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- VIM | c.1172T>A p.M391K | Missense Mutation (SNP) | VAF 169/770 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- WDR17 | c.2420G>A p.G807D | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- WDR64 | c.2944T>A p.F982I | Missense Mutation (SNP) | VAF 37/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WIZ | c.5632G>T p.A1878S (on ENST00000673675 / NM_001371589.1; = p.A783S on NM_021241.3) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- XPO1 | c.2617C>G p.L873V | Missense Mutation (SNP) | VAF 30/643 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ZAN | c.3871T>C p.C1291R | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZFAND4 | c.1789G>T p.G597W | Missense Mutation (SNP) | VAF 22/475 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2
- ZFHX4 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); called by muse, mutect2
- ZFHX4 | c.5895A>T p.Q1965H | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZKSCAN7 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- ZKSCAN8 | c.744G>T p.R248S | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ZNF148 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 177/718 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- ZNF208 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 55/473 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, varscan2
- ZNF397 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF571 | c.1695G>T p.R565S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- ZNF662 | c.328G>T p.V110F | Missense Mutation (SNP) | VAF 76/344 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF790 | c.1405C>A p.Q469K | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF831 | c.2261G>T p.R754M | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ZZEF1 | c.7736A>G p.Y2579C | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ABCA13 | c.546A>T p.L182= | Silent (SNP) | VAF 143/568 reads (25%) | called by muse, mutect2, varscan2
- ABCA13 | c.6636G>A p.L2212= | Silent (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- AC024598.1 | c.1185T>C p.N395= | Silent (SNP) | VAF 86/473 reads (18%) | catalogued as rs147223030; called by muse, mutect2, varscan2
- ADAMTS20 | c.4848C>T p.T1616= | Silent (SNP) | VAF 31/246 reads (13%) | catalogued as rs145474293; called by muse, mutect2, varscan2
- AHCTF1 | c.2883G>A p.L961= (on ENST00000366508; = p.L935= on NM_015446.5) | Silent (SNP) | VAF 21/256 reads (8%) | catalogued as rs762221394; called by muse, mutect2
- AMELX | c.486C>T p.F162= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV61627665; called by muse, mutect2, varscan2
- ANK3 | c.63C>G p.G21= | Silent (SNP) | VAF 18/289 reads (6%) | called by muse, mutect2
- BABAM2 | c.738C>T p.L246= | Silent (SNP) | VAF 23/455 reads (5%) | called by muse, mutect2
- BOD1L1 | c.348C>T p.N116= | Silent (SNP) | VAF 54/343 reads (16%) | catalogued as rs368418760, COSV50014512; called by muse, mutect2, varscan2
- CLEC1B | c.184C>T p.L62= | Silent (SNP) | VAF 57/378 reads (15%) | catalogued as rs763278564; called by muse, mutect2, varscan2
- COL16A1 | c.1140G>A p.K380= | Silent (SNP) | VAF 36/233 reads (15%) | called by muse, mutect2, varscan2
- COL23A1 | c.1344C>A p.G448= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV66796863; called by muse, mutect2, varscan2
- COL26A1 | c.1245C>G p.A415= (on ENST00000313669 / NM_001278563.3; = p.A413= on NM_133457.4) | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- CPSF1 | c.2925C>T p.F975= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as rs73717823; called by muse, mutect2
- DCAF4L2 | c.990G>T p.A330= | Silent (SNP) | VAF 67/184 reads (36%) | catalogued as COSV100150825; called by muse, mutect2, varscan2
- DCDC1 | c.5268C>A p.I1756= (on ENST00000597505 / NM_001367979.1; = p.I863= on NM_020869.3) | Silent (SNP) | VAF 28/329 reads (9%) | called by muse, mutect2
- DCDC1 | c.2826G>A p.Q942= (on ENST00000597505 / NM_001367979.1; = p.Q49= on NM_020869.3) | Silent (SNP) | VAF 42/500 reads (8%) | catalogued as COSV60304508, COSV60306009; called by muse, mutect2
- DOP1B | c.2004G>T p.T668= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- DSTYK | c.1815G>T p.R605= | Silent (SNP) | VAF 12/70 reads (17%) | called by muse, varscan2
- EDN1 | c.123C>G p.P41= | Silent (SNP) | VAF 25/372 reads (7%) | called by muse, mutect2
- EP400 | c.7278G>T p.T2426= | Silent (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- FAM174C | c.138G>A p.T46= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, varscan2
- FAM71B | c.396C>A p.I132= | Silent (SNP) | VAF 28/209 reads (13%) | called by muse, mutect2, varscan2
- FAT3 | c.4470G>A p.K1490= | Silent (SNP) | VAF 94/755 reads (12%) | catalogued as COSV53154099; called by muse, mutect2, varscan2
- FBN2 | c.6132C>A p.P2044= | Silent (SNP) | VAF 90/502 reads (18%) | called by muse, mutect2, varscan2
- FER1L6 | c.1632C>A p.A544= | Silent (SNP) | VAF 34/354 reads (10%) | called by muse, mutect2
- FIP1L1 | c.33G>A p.S11= | Silent (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- FNBP4 | c.379C>T p.L127= | Silent (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- FNDC3B | c.2304A>G p.G768= | Silent (SNP) | VAF 79/365 reads (22%) | called by muse, mutect2, varscan2
- FUCA1 | c.330C>T p.F110= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- FUT9 | c.141G>T p.V47= | Silent (SNP) | VAF 39/371 reads (11%) | called by muse, mutect2, varscan2
- H1-2 | c.27C>T p.P9= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs755518803, COSV59190085, COSV59191897; called by mutect2, varscan2
- HGFAC | c.936C>T p.S312= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs771972328, COSV66977072; called by muse, mutect2, varscan2
- HOMER1 | c.840A>G p.L280= | Silent (SNP) | VAF 53/467 reads (11%) | catalogued as rs1178163613; called by muse, mutect2, varscan2
- ICAM2 | c.246C>T p.N82= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as rs778964288; called by muse, mutect2, varscan2
- IQSEC3 | c.855C>A p.A285= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs1555083264; called by muse, mutect2, varscan2
- KCTD8 | c.1128C>A p.A376= | Silent (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- KRT36 | c.324G>A p.L108= | Silent (SNP) | VAF 26/282 reads (9%) | called by muse, mutect2
- LILRA1 | c.1275C>A p.T425= | Silent (SNP) | VAF 38/438 reads (9%) | catalogued as rs1427441392; called by muse, mutect2
- LRP1 | c.282G>C p.G94= | Silent (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- MAML1 | c.408G>T p.G136= | Silent (SNP) | VAF 30/189 reads (16%) | called by muse, mutect2, varscan2
- MAP2K6 | c.891G>A p.K297= | Silent (SNP) | VAF 22/424 reads (5%) | called by muse, mutect2
- MAST4 | c.5874A>T p.P1958= (on ENST00000403625 / NM_001164664.2; = p.P1769= on NM_015183.3) | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- MCF2L | c.1815G>T p.R605= (on ENST00000375608; = p.R573= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- MGAM2 | c.49T>C p.L17= | Silent (SNP) | VAF 35/492 reads (7%) | called by muse, mutect2
- MIA2 | c.792A>T p.L264= | Silent (SNP) | VAF 91/456 reads (20%) | called by muse, mutect2, varscan2
- MRTFB | c.306G>T p.R102= | Silent (SNP) | VAF 69/359 reads (19%) | catalogued as rs1329731194; called by muse, mutect2, varscan2
- MUC17 | c.1851C>A p.T617= | Silent (SNP) | VAF 51/239 reads (21%) | catalogued as rs899877096; called by muse, mutect2, varscan2
- MYO10 | c.1485G>A p.L495= | Silent (SNP) | VAF 80/418 reads (19%) | called by muse, mutect2, varscan2
- NASP | c.873T>A p.T291= | Silent (SNP) | VAF 27/333 reads (8%) | called by muse, mutect2
- NBPF4 | c.1524C>T p.T508= | Silent (SNP) | VAF 50/666 reads (8%) | catalogued as rs866894835; called by muse, mutect2
- NFATC2 | c.1623G>T p.R541= | Silent (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- NMUR2 | c.636C>A p.I212= | Silent (SNP) | VAF 28/346 reads (8%) | catalogued as rs1011768346; called by muse, mutect2
- NPAP1 | c.2232C>A p.G744= | Silent (SNP) | VAF 13/203 reads (6%) | catalogued as COSV61508273; called by muse, mutect2
- NRDE2 | c.1833C>T p.P611= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs550649701; called by muse, mutect2
- OGFR | c.1560G>A p.E520= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as COSV99284575; called by muse, mutect2, varscan2
- ONECUT1 | c.501C>A p.P167= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- OR4C46 | c.363T>C p.Y121= | Silent (SNP) | VAF 36/340 reads (11%) | called by muse, mutect2, varscan2
- PCDHA2 | c.87C>A p.G29= | Silent (SNP) | VAF 45/193 reads (23%) | catalogued as COSV65365450; called by muse, mutect2, varscan2
- PCDHB16 | c.1971G>A p.T657= | Silent (SNP) | VAF 35/266 reads (13%) | catalogued as rs1479964948; called by muse, mutect2, varscan2
- PCDHB8 | c.1326G>T p.V442= | Silent (SNP) | VAF 82/2094 reads (4%) | catalogued as COSV50753685; called by muse, mutect2
- PLAG1 | c.474T>G p.T158= | Silent (SNP) | VAF 150/494 reads (30%) | called by muse, mutect2, varscan2
- PLPPR4 | c.246G>T p.V82= | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- PRDM9 | c.747G>T p.G249= | Silent (SNP) | VAF 77/572 reads (13%) | called by muse, mutect2, varscan2
- PRR14L | c.5643G>T p.V1881= | Silent (SNP) | VAF 18/244 reads (7%) | catalogued as COSV57886789; called by muse, mutect2
- PRSS56 | c.873C>A p.T291= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- RAG1 | c.468C>A p.A156= | Silent (SNP) | VAF 41/354 reads (12%) | catalogued as COSV100201034; called by muse, mutect2, varscan2
- REELD1 | c.858C>T p.L286= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- RGS20 | c.483C>T p.A161= | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- RGS9 | c.921C>T p.I307= | Silent (SNP) | VAF 96/614 reads (16%) | called by muse, mutect2, varscan2
- RTN1 | c.1866C>T p.S622= | Silent (SNP) | VAF 61/492 reads (12%) | catalogued as rs772270786, COSV50721100; called by muse, mutect2, varscan2
- RYR3 | c.6699G>A p.R2233= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs1306167957; called by muse, mutect2
- SCN5A | c.5229G>T p.G1743= (on ENST00000333535 / NM_198056.3; = p.G1742= on NM_000335.5) | Silent (SNP) | VAF 27/224 reads (12%) | called by muse, mutect2, varscan2
- SLC1A7 | c.273C>T p.L91= | Silent (SNP) | VAF 31/213 reads (15%) | catalogued as rs776184320, COSV65194936; called by muse, mutect2, varscan2
- SLC5A12 | c.1212T>G p.G404= | Silent (SNP) | VAF 75/472 reads (16%) | catalogued as rs1230942241; called by muse, mutect2, varscan2
- SLC5A6 | c.423G>C p.V141= | Silent (SNP) | VAF 57/468 reads (12%) | called by muse, mutect2, varscan2
- SLFN14 | c.1732T>C p.L578= | Silent (SNP) | VAF 28/586 reads (5%) | called by muse, mutect2
- SLIT1 | c.3855C>G p.L1285= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SNRPC | c.345A>T p.P115= | Silent (SNP) | VAF 20/211 reads (9%) | called by muse, mutect2
- SNTG2 | c.111C>A p.S37= | Silent (SNP) | VAF 58/318 reads (18%) | called by muse, mutect2, varscan2
- SNX15 | c.339C>T p.L113= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV57247466; called by muse, mutect2, varscan2
- SOWAHA | c.639G>A p.Q213= | Silent (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- SPAM1 | c.222T>C p.S74= | Silent (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2, varscan2
- SPANXN2 | c.537G>A p.E179= | Silent (SNP) | VAF 31/147 reads (21%) | called by muse, varscan2
- SYNPO | c.645C>T p.L215= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- TACR3 | c.171G>T p.A57= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1178329837, COSV59199696, COSV59201722; called by muse, mutect2, varscan2
- THAP3 | c.159C>T p.V53= | Silent (SNP) | VAF 15/210 reads (7%) | catalogued as COSV99275697; called by muse, mutect2
- TMPRSS13 | c.531C>G p.A177= | Silent (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- TSGA10 | c.2037A>T p.R679= | Silent (SNP) | VAF 41/288 reads (14%) | called by muse, mutect2, varscan2
- TUBB8 | c.657A>C p.T219= | Silent (SNP) | VAF 86/376 reads (23%) | called by muse, varscan2
- ZDBF2 | c.3885C>T p.S1295= | Silent (SNP) | VAF 30/456 reads (7%) | catalogued as rs746088933; called by muse, mutect2
- ZNF155 | c.6C>T p.T2= | Silent (SNP) | VAF 43/187 reads (23%) | called by muse, mutect2, varscan2
- ZNF25 | c.1212G>T p.G404= | Silent (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- ZNF777 | c.1995G>C p.T665= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as COSV56098739; called by muse, mutect2, varscan2
- ZPBP | c.432T>C p.Y144= | Silent (SNP) | VAF 42/456 reads (9%) | called by muse, mutect2
- AC010507.1 | chr19:200430 C>T | 3'Flank (SNP) | VAF 3/17 reads (18%) | catalogued as rs1413345033; called by mutect2, varscan2
- AC244517.10 | c.36-10420C>G | Intron (SNP) | VAF 42/369 reads (11%) | called by muse, mutect2, varscan2
- ATP8B2 | c.1133+22G>T | Intron (SNP) | VAF 115/397 reads (29%) | called by muse, mutect2, varscan2
- BOD1P2 | n.148C>A | RNA (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- CAPRIN1 | c.1-72C>T | Intron (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- CASP4 | c.*83T>G | 3'UTR (SNP) | VAF 38/574 reads (7%) | called by muse, mutect2
- CTSL3P | n.522G>T | RNA (SNP) | VAF 43/365 reads (12%) | called by muse, mutect2, varscan2
- DMD | c.9808-15C>T | Intron (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- DTNA | c.*2607T>A | 3'UTR (SNP) | VAF 70/324 reads (22%) | called by muse, mutect2, varscan2
- EDIL3 | c.1137+12069G>T | Intron (SNP) | VAF 21/228 reads (9%) | catalogued as COSV56890120; called by muse, mutect2
- FAM217A | c.-81G>T | 5'UTR (SNP) | VAF 9/38 reads (24%) | catalogued as rs1043858533; called by muse, mutect2, varscan2
- FLT4 | c.2168-46G>T | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99987968; called by muse, mutect2
- FRS3 | chr6:41780360 G>C | 5'Flank (SNP) | VAF 22/242 reads (9%) | called by muse, mutect2
- GATA4 | chr8:11761507 C>A | 3'Flank (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- GBA3 | c.59-8310T>C | Intron (SNP) | VAF 36/444 reads (8%) | catalogued as rs1391196074; called by muse, mutect2
- GNG2 | c.-30+16851C>T | Intron (SNP) | VAF 18/526 reads (3%) | catalogued as rs1456085234; called by muse, mutect2
- H2BP2 | n.1061+485G>C | Intron (SNP) | VAF 14/48 reads (29%) | called by mutect2, varscan2
- HGFAC | c.1103-193G>T | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- HNRNPLL | c.-212C>A | 5'UTR (SNP) | VAF 42/167 reads (25%) | catalogued as rs760483876; called by muse, mutect2, varscan2
- HSP90AA4P | n.2188C>T | RNA (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- IFT81 | c.1188+4811G>T | Intron (SNP) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- IGF2 | c.326-520G>A | Intron (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- IL13RA1 | c.1009+3370G>T | Intron (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- ISCA1 | c.242-1573A>T | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- KNOP1P1 | n.78G>T | RNA (SNP) | VAF 18/285 reads (6%) | called by muse, mutect2
- LAMA4 | c.1551+9G>T | Intron (SNP) | VAF 58/626 reads (9%) | called by muse, mutect2
- LONRF3 | c.1060-2393T>C | Intron (SNP) | VAF 48/195 reads (25%) | called by muse, mutect2, varscan2
- MAP4K2 | c.96+13G>T | Intron (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- MEIS3P1 | n.824G>C | RNA (SNP) | VAF 42/298 reads (14%) | called by muse, mutect2, varscan2
- MIR384 | n.31G>A | RNA (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- MIR485 | n.55G>C | RNA (SNP) | VAF 11/78 reads (14%) | catalogued as rs769004546; called by muse, mutect2, varscan2
- MT1H | c.-47G>T | 5'UTR (SNP) | VAF 50/309 reads (16%) | called by muse, mutect2, varscan2
- NDOR1 | c.-8G>T | 5'UTR (SNP) | VAF 8/121 reads (7%) | catalogued as rs1166850126; called by muse, mutect2
- NECAP2 | c.489+997_489+998del | Intron (DEL) | VAF 32/177 reads (18%) | called by mutect2, pindel, varscan2
- OR9Q1 | c.-15+53489C>A | Intron (SNP) | VAF 43/298 reads (14%) | catalogued as rs1207836321; called by muse, mutect2, varscan2
- PAX5 | c.781-7429T>A | Intron (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2394+1453G>A | Intron (SNP) | VAF 38/294 reads (13%) | called by muse, mutect2, varscan2
- PEX1 | c.-49G>T | 5'UTR (SNP) | VAF 6/27 reads (22%) | catalogued as rs747424358; called by mutect2, varscan2
- PFKFB1 | chrX:54998416 A>G | 5'Flank (SNP) | VAF 39/236 reads (17%) | called by muse, mutect2, varscan2
- PRMT1 | c.759+46G>A | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3751A>T | RNA (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- RPSAP52 | n.965C>G | RNA (SNP) | VAF 38/304 reads (13%) | called by muse, mutect2, varscan2
- RTL8B | c.*129C>G | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- SAMHD1 | c.1642-51G>T | Intron (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- SAMSN1 | c.235+190C>A | Intron (SNP) | VAF 28/226 reads (12%) | catalogued as rs1237065063; called by muse, mutect2, varscan2
- SIX2 | c.-43C>A | 5'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- SLC6A2 | c.-39C>T | 5'UTR (SNP) | VAF 16/134 reads (12%) | catalogued as rs761522601; called by muse, varscan2
- SLURP2 | c.*106C>A | 3'UTR (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25091974 C>A | 3'Flank (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- SUN1 | c.659-1333T>C | Intron (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- TBX2 | chr17:61412341 A>G | 3'Flank (SNP) | VAF 7/23 reads (30%) | catalogued as rs926770182; called by muse, mutect2, varscan2
- TEX101 | c.-12C>A | 5'UTR (SNP) | VAF 59/200 reads (30%) | catalogued as COSV99494931; called by muse, mutect2, varscan2
- TEX51 | c.539+10C>A | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- TMEM135 | c.*2219A>G | 3'UTR (SNP) | VAF 68/376 reads (18%) | catalogued as rs1371597991; called by muse, mutect2, varscan2
- TMEM30CP | n.219T>C | RNA (SNP) | VAF 95/369 reads (26%) | called by muse, mutect2, varscan2
- UQCRB | c.*3393G>A | 3'UTR (SNP) | VAF 169/514 reads (33%) | called by muse, mutect2, varscan2
- Unknown | chr17:43379228 G>A | IGR (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- VSTM2A | c.634+3771T>C | Intron (SNP) | VAF 38/700 reads (5%) | called by muse, mutect2
- WT1 | chr11:32438420 C>A | 5'Flank (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- XRCC5 | c.-68G>C | 5'UTR (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
